Gene-level copy-number profile of tumor specimen TCGA-HU-A4H2-01A from TCGA case TCGA-HU-A4H2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.9 years (21,496 days).
Specimen TCGA-HU-A4H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7a32fbb0-3527-4652-b1be-324e7a53c392.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4H2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a94c885-cb1e-4c5b-bc05-2d7dc37e6057

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 860; copy number 2: 6,982; copy number 3: 20,136; copy number 4: 15,721; copy number 5: 13,013; copy number 6: 1,516; copy number 7: 239; copy number 8: 778; copy number 11: 320; copy number 12: 225; copy number 14: 6; copy number 20: 8; copy number 42: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4H2-01A-11D-A253-01): tumor purity 0.49, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,592 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:52,144,349–53,418,737, 52 genes, copy number 12–20: MIR206, LINCMD1, MIR133B, IL17A, IL17F, SLC25A20P1, MCM3, PAQR8, EFHC1, TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3, GSTA9P, AL121969.1, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3.
- chr7:70,972–13,872,513, 250 genes, copy number 8 (broad region; genes not listed).
- chr7:83,955,777–93,574,730, 112 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr7:99,173,574–108,130,361, 278 genes, copy number 8–14 (broad region; genes not listed).
- chr8:11,368,402–11,438,658, 1 gene, copy number 42 (within-gene range 4–42): FAM167A-AS1.
- chr8:11,392,411–11,896,870, 15 genes, copy number 42: RNU6-1084P, FAM167A, AF131216.5, BLK, AC022239.1, LINC00208, AC022239.2, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1.
- chr17:36,116,177–38,405,593, 72 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr17:65,457,541–65,641,033, 3 genes, copy number 7: LINC02563, AXIN2, AC004805.1.
- chr17:65,644,308–65,655,395, 2 genes, copy number 7: AC004805.3, AC004805.2.
- chr19:27,638,483–31,349,436, 72 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr19:42,198,598–46,077,118, 202 genes, copy number 7–12 (broad region; genes not listed).
- chr19:51,685,363–58,605,223, 533 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 860. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
